Somatic mutation profile of tumor specimen TCGA-FC-A4JI-01A (aliquot TCGA-FC-A4JI-01A-11D-A257-08) from TCGA case TCGA-FC-A4JI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.0 years (25,931 days).
Specimen TCGA-FC-A4JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cba21ae-3cf1-44a1-862a-e4df866dbabc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-A4JI-10A (Blood Derived Normal), aliquot TCGA-FC-A4JI-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c4dbf6-18fd-43e8-b0be-92e27925ca25

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Splice Region 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.754_774del p.N252_C258del | In Frame Del (DEL) | VAF 10/38 reads (26%) | hotspot (GDC flag); called by mutect2, pindel
- C2orf80 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100378389, COSV58015956; called by muse, mutect2, varscan2
- CENPJ | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs141856342; called by muse, mutect2, varscan2
- CERS5 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1274790322, COSV58188670; called by muse, mutect2, varscan2
- GNAI2 | c.246G>C p.M82I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56493142; called by muse, mutect2, varscan2
- KIF13A | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52445769; called by muse, mutect2, varscan2
- MAGEB4 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs868207052, COSV66775412; called by muse, mutect2
- MYCBP2 | c.481A>G p.I161V (on ENST00000357337; = p.I199V on NM_015057.5) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV100632326, COSV62012897; called by muse, mutect2, varscan2
- MYO15A | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs767388755, COSV52751423; called by muse, mutect2, varscan2
- NNT | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV52923564; called by muse, mutect2, varscan2
- PADI3 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV64934162; called by muse, mutect2, varscan2
- PRKCZ | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66066316; called by muse, mutect2, varscan2
- PTPRN | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781479935, COSV55345421; called by muse, mutect2, varscan2
- RAD52 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1449954844, COSV57272499; called by muse, mutect2
- RNF213 | c.8546C>T p.A2849V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771738412, COSV60392922; called by muse, mutect2, varscan2
- SLC44A5 | c.54T>C p.G18= | Splice Region (SNP) | VAF 43/207 reads (21%) | catalogued as COSV63760081; called by muse, mutect2, varscan2
- ST3GAL1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | PolyPhen benign (0.39); catalogued as rs762645739, COSV60611202; called by muse, mutect2, varscan2
- STAU2 | c.148A>G p.T50A (on ENST00000524300 / NM_001164380.2; = p.T18A on NM_014393.2) | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as COSV62474591; called by muse, mutect2, varscan2
- TP53BP1 | c.5431C>T p.R1811* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as rs745781646, COSV53018164; called by muse, mutect2, varscan2
- ACACA | c.6085A>G p.T2029A | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNTNAP3 | c.3779G>C p.C1260S | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KBTBD7 | c.1257del p.D420Ifs*32 | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- AHI1 | c.492C>T p.G164= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs777755428, COSV55624575, COSV55629156; called by muse, mutect2, varscan2
- BMP10 | c.1041C>T p.Y347= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs557332981, COSV54894419; called by muse, mutect2, varscan2
- HTT | c.8352C>T p.H2784= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs751199242, COSV61859086; called by muse, mutect2, varscan2
- LRP2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs111909155; called by muse, mutect2, varscan2
- LRRTM1 | c.402G>A p.R134= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV54439425; called by muse, mutect2, varscan2
- NOP9 | c.205C>T p.L69= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV55383628; called by muse, mutect2, varscan2
- PRKAR1A | c.426T>C p.D142= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs3730371, COSV62235303; called by muse, mutect2, varscan2
- PSG7 | c.222C>T p.D74= | Silent (SNP) | VAF 50/207 reads (24%) | catalogued as COSV68444576; called by muse, mutect2, varscan2
- ZEB2 | c.2323T>C p.L775= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as rs1464061857, COSV57953467, COSV57963936; called by muse, mutect2, varscan2
- ZNF236 | c.2439A>G p.A813= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV53484351; called by muse, mutect2, varscan2
- TRO | c.*36C>G | 3'UTR (SNP) | VAF 16/26 reads (62%) | catalogued as rs763747412, COSV51499423; called by muse, mutect2, varscan2
